CCDI case PBCNYT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/79caece2-7653-4926-bc27-69bc45c4113d

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 18.5 years (6,764 days).

Biospecimens (2 samples)
- Sample 0DWTA8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWTBZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
